Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A1G4, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A1G4-01A (Primary Tumor).

[page 1 of 4]
Carcinoma, infiltrating ductal, NOS 8500/3
Site: Breast, NOS C50.9 1/25/11 lw

Chief of Pathology

Phone

Fax

Specimen:

Received:

Spec Type: SURGICAL P

Status:

Subm Dr:

Recd:

BREAST CANCER INVASIVE

DATE:

DOCTOR(S):

PROCEDURE:

- A. RT BREAST DEEP MARGIN
- B. LT BREAST
- C. RT PREAST AND AXILLARY NODES

RECEIVED

RTS.

LABELED

RIGHT DEEP MARGIN INK MARKS NEW
MEASURING 4.8 X 2.2 X 0.6 CM IN GREATEST DIMENSIONS. ONE SIDE OF THE
SPECIMEN IS RECEIVED MARKED WITH BLUE INK. THIS SIDE IS FURTHER MARKED
WITH BLUE INK WITH A PERIMETER OF RED INK. THE SPECIMEN IS SECTIONED AND
ID LABELED A1 THROUGH A3.

PA

LABELED

LEFT BREAST IS A SIMPLE
MEASURING 24.5 X 21 X 3.8 CM. A SUTURE DENOTES 12
O'CLOCK. THE NIPPLE IS FLAT WITHIN A 23.7 X 15.3 CM SKIN ELLIPSE. IN
THE 9 O'CLOCK AREA OF THE BREAST THERE IS A 0.5 CM IN DIAMETER
FLOWER-SHAPED RED-BROWN SKIN LESION. THE SUPERFICIAL ASPECT IS MARKED
WITH BLUE INK, THE DEEP WITH BLACK INK. SECTIONING REVEALS THE SPECIMEN
TO CONSIST OF BLAND YELLOW FATTY TISSUE WITH FINE FIBROUS BANDS. THERE
ARE NODULAR FIRM AREAS NOTED CENTRALLY THAT DO NOT FORM DISCRETE MASSES.
SECTIONS ARE SUBMITTED AS FOLLOWS: B1--NIPPLE AND DESCRIBED SKIN LESION,
B2--CENTRAL DEEP MARGIN, B3 AND B4--UPPER OUTER QUADRANT, B5 AND
B6--UPPER INNER QUADRANT, B7 AND B8--LOWER INNER QUADRANT, B9 AND
B10--LOWER OUTER QUADRANT, B11--TISSUE CENTRAL. NOTE THAT B1, B3, B5,
B7, B9, AND B11 ARE MIRROR IMAGE TISSUE TAKEN PER PROTOCOL.

ADDITIONAL SECTIONS FROM THE LOWER INNER QUADRANT ARE SUBMITTED LABELED
B12 THROUGH B14, A SECTION FROM THE SUBAREOLAR AREA IN B15, AND
ADDITIONAL TISSUE FROM THE UPPER OUTER QUADRANT B16 AND 17.

PART C RECEIVED LABELED

RIGHT BREAST AND AXILLARY LYMPH
NODE IS A RIGHT MODIFIED RADICAL MASTECTOMY SPECIMEN WITH FRAGMENTS OF
LOOSE TISSUE WHICH ALSO DEMONSTRATE PALPABLE LYMPH NODES. THE OVERALL
DIMENSIONS ARE 30 X 22 X 4.3 CM. THE NIPPLE IS FLATTENED. IMMEDIATELY

[page 2 of 4]
Chief of Pathology

Phone

Fax

Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Spec Type: SURGICAL P

Subm Dr:

(Continued)

LATERAL TO THE NIPPLE IS A PALPABLE MASS. THE SKIN ELLIPSE MEASURES 22.6 X 14.0 CM. A SMALL RAISED PIGMENTED LESION IS FOUND IN THE LOWER OUTER QUADRANT ADJACENT TO THE SKIN RESECTION MARGIN MEASURING 0.4 CM IN DIAMETER. THE SUPERFICIAL ASPECT IS MARKED IN BLUE INK, THE DEEP ASPECT WITH BLACK INK. WHERE THE AXILLARY TAIL IS REMOVED, IT IS MARKED IN RED AND DOES NOT REPRESENT TRUE MARGIN. THE AXILLARY TAIL IS EXAMINED FOR LYMPH NODES. IN THE LOW AXILLARY TAIL, THERE IS A 2.8 CM CENTRALLY FAT-REPLACED LYMPH NODE WITH A COIL CLIP. ONE HALF IS SUBMITTED PER PROTOCOL. THE REMAINDER IS SUBMITTED AS C1. A SECOND LOW NODE IS GROSSLY POSITIVE 1.6 CM IN GREATEST DIMENSION. ONE HALF IS SUBMITTED AS C2 WITH THE REMAINDER SUBMITTED PER PROTOCOL. ADDITIONAL NODES ARE THEN SUBMITTED AS FOLLOWS: C3--ONE HALF GROSSLY UNREMARKABLE LYMPH NODE (MIRROR IMAGE TO PROTOCOL), C4--TWO NODES EACH BISECTED, C5--ONE NODE BISECTED, C6--ONE NODE BISECTED, C7--ONE NODE BISECTED, C8--TWO NODES EACH BISECTED, C9--FOUR NODES, C10--TWO NODES EACH BISECTED, C11 AND C12--ONE NODE TOTAL. SECTIONING REVEALED THE BREAST TO CONSIST OF BLAND YELLOW FATTY TISSUE WITH FINE FIBROUS BANDS. THE PALPABLE MASS IS ILL-DEFINED WITH PINK-TAN TISSUE INTERSPERSED IN THE YELLOW-FATTY TISSUE. THIS EXTENDS FROM THE SUBAREOLAR AREA IN THE LOWER OUTER QUADRANT MEASURING 6 CM FROM MEDIAL TO LATERAL BY PALPATION 6.5 CM FROM SUPERIOR TO INFERIOR AND 4 CM FROM SUPERFICIAL TO DEEP IN AN ILL-DEFINED MANNER. GROSSLY THIS EXTENDS TO WITHIN 0.5 CM OF THE DEEP MARGIN. SECTIONS ARE SUBMITTED AS FOLLOWS: C13--NIPPLE (MIRROR IMAGE TO PROTOCOL), C14 AND C15--LESION AND CLOSEST GROSS DEEP MARGIN, C16--THE MOST LATERAL ASPECT OF THE LESION (MIRROR IMAGE TO PROTOCOL), C17--THE MOST CENTRAL AND MEDIAL PORTION OF THE LESION (MIRROR IMAGE TO PROTOCOL), NOTE THAT C16 AND C17 ARE 6 CM APART, C18--TUMOR (MIRROR IMAGE TO PROTOCOL), C19--THE MOST INFERIOR ASPECT OF THE LESION WITH INFERIOR SUPERFICIAL MARGIN, C20--THE SUPERIOR PORTION OF THE LESION OR ADJACENT TO MARGIN CENTRAL SPECIMEN, C21--UPPER OUTER QUADRANT, C22--LOWER INNER QUADRANT, C23--UPPER INNER QUADRANT, C24 AND C25--ADDITIONAL SECTIONS OF CENTRAL TUMOR (MIRROR IMAGE TO PROTOCOL).

PROCEDURES:

88307/2, 88309, A BLK/3, B BLK/17, C BLK/25, ER PR KI67 HER2

PART A RIGHT BREAST DEEP MARGIN REEXCISION: FIBROADIPOSE TISSUE AND SKELETAL MUSCLE WITH NO EVIDENCE OF MALIGNANCY. THE NEW INKED MARGIN IS FREE OF NEOPLASM.

PART B LEFT BREAST, SIMPLE MASTECTOMY:

1. INFILTRATING LOBULAR CARCINOMA, NUCLEAR GRADE I WITH LOW MITOTIC INDEX, IDENTIFIED IN THE LOWER INNER QUADRANT WITH AN ESTIMATED TUMOR DIMENSION OF 21 MM (SLIDES B7, B8, B12-14).

[page 3 of 4]
Chief of Pathology

Phone

Fax

Patient: [REDACTED]

(Continued)

Specimen:

Received:

Spec Type: SURGICAL P
(Continued)

Status:

Subm Dr:

Req#:

2. THE NIPPLE AND DEEP MARGIN ARE FREE OF NEOPLASM.
3. LYMPHATIC INVASION IS NOT IDENTIFIED.
4. PROLIFERATIVE FIBROCYSTIC DISEASE WITH A FOCUS OF LOBULAR CARCINOMA IN SITU IDENTIFIED IN THE UPPER OUTER QUADRANT ALONG WITH SCLEROSING ADENOSIS, DUCT HYPERPLASIA OF THE USUAL TYPE, APOCRINE METAPLASIA AND CYST FORMATION.

PART C RIGHT BREAST, MODIFIED RADICAL MASTECTOMY:

1. LARGE MODERATELY DIFFERENTIATED INTRADUCTAL AND INFILTRATING DUCT CARCINOMA, NUCLEAR GRADE II WITH LOW MITOTIC INDEX WITH FOCI OF MUCINOUS DIFFERENTIATION SPANNING A DISTANCE OF 65 MM.
2. THE DEEP MARGIN IS FREE OF NEOPLASM. DUCTAL CARCINOMA IN SITU INVOLVES THE NIPPLE.
3. LYMPHATIC INVASION IS PRESENT.
4. METASTATIC CARCINOMA TO 1 OF 15 AXILLARY LYMPH NODES. ONE LYMPH NODE DEMONSTRATES PREVIOUS BIOPSY SITE CHANGE BUT NO RESIDUAL NEOPLASM.
5. HEMANGIOMA, SKIN OF BREAST.

RECEPTOR AND PROGNOSTIC FACTOR DETERMINATION WILL BE PERFORMED ON BLOCK B7. -

ESTROGEN RECEPTOR: POSITIVE
Nuclei Stained: 100%
Intensity: 3

Reference Range: Negative <1%
Positive >= 1%

PROGESTERONE RECEPTOR: NEGATIVE
Nuclei Stained: 0
Intensity: 1

Reference Range: Negative <1%
Positive >= 1%

Her-2/neu: NEGATIVE
Score: 1+

Reference Range: Negative 0 - 1+
Equivocal 2+

[page 4 of 4]
Chief of Pathology

Phone

Fax (

Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Spec Type: SURGICAL P
(Continued)

Subm Dr:

Positive 3+

Ki-67: LOW

Nuclei Stained: 3%

3

Intensity:

Reference Range: Low <10%

Borderline 10-20%

High >20%

Electronically signed by:

See full scanned report for details.

Test performed at: (

1

1. SENT TO:
2. REQUESTED BY:
3. DATE SENT:
4. METHOD OF TRANSPORTATION:
5. NO. OF BLOCKS:
7. MATERIAL(S) TO BE RETURNED:
14. SPECIMEN SENT(Y/N):

Signed _____

(prelim.)

_____(signature on file)_____

Source: NCI Genomic Data Commons file 32ffb960-ca14-4aea-a8f4-2148430aa5af (TCGA-A2-A1G4.5AD3B697-F097-496C-978B-F73BDA5394A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).